Gene-level copy-number profile of tumor specimen ALCH-B1YF-TTR1-A from ALCHEMIST case ALCH-B1YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,786 days).
Specimen ALCH-B1YF-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 860c485f-dfdb-43c7-9241-abf5c9c4b790.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,328 have no estimate.
https://portal.gdc.cancer.gov/files/30db50da-d744-41f2-87eb-970c19289219

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 61; copy number 2: 1,803; copy number 3: 9,362; copy number 4: 23,979; copy number 5: 17,442; copy number 6: 4,086; copy number 7: 433; copy number 8: 341; copy number 9: 63; copy number 10: 29; copy number 11: 46; copy number 12: 5; copy number 13: 6; copy number 14: 24; copy number 15: 277; copy number 17: 5; copy number 18: 13; copy number 19: 24; copy number 21: 3; copy number 23: 35; copy number 24: 4; copy number 25: 115; copy number 26: 58; copy number 27: 8; copy number 28: 2; copy number 30: 6; copy number 33: 24; copy number 37: 4; copy number 41: 2; copy number 44: 14; copy number 52: 15; copy number 57: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,212,373, 4 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr10:15,015,370–15,021,863, 1 gene: DCLRE1CP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 783 genes in 68 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:131,025–195,411, 10 genes, copy number 11 (within-gene range 6–11): CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr1:1,137,017–1,170,343, 3 genes, copy number 9–11: LINC01342, MIR200B, AL390719.2.
- chr1:1,203,508–1,206,592, 1 gene, copy number 13: TNFRSF18.
- chr1:1,216,909–1,232,067, 1 gene, copy number 10: SDF4.
- chr1:1,280,436–1,309,609, 2 genes, copy number 10–14 (within-gene range 6–14): SCNN1D, ACAP3.
- chr1:1,331,280–1,349,418, 3 genes, copy number 10–11: TAS1R3, DVL1, MIR6808.
- chr1:1,399,520–1,427,787, 7 genes, copy number 9: MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B.
- chr1:1,512,162–1,540,624, 2 genes, copy number 11: ATAD3A, TMEM240.
- chr1:1,915,108–1,919,279, 2 genes, copy number 9: CALML6, TMEM52.
- chr1:2,530,064–2,569,888, 4 genes, copy number 11 (within-gene range 6–11): AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2.
- chr1:3,454,665–3,487,627, 2 genes, copy number 9–13: ARHGEF16, AL512413.1.
- chr4:1,113,639–1,153,726, 3 genes, copy number 11 (within-gene range 7–11): AC092535.4, TMED11P, AC092535.1.
- chr4:1,166,932–1,208,962, 2 genes, copy number 9–11: SPON2, AC092535.5.
- chr8:78,805,293–81,533,275, 57 genes, copy number 11–33 (within-gene range 4–33): AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12.
- chr8:85,744,543–86,818,558, 29 genes, copy number 25: REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1.
- chr8:92,668,660–92,879,502, 4 genes, copy number 37: AC104211.1, FLJ46284, AC104211.2, AC117834.2.
- chr8:93,029,751–99,895,121, 136 genes, copy number 17–44 (broad region; genes not listed).
- chr8:115,950,511–116,849,463, 6 genes, copy number 30 (within-gene range 3–30): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23.
- chr8:123,851,987–128,564,679, 79 genes, copy number 18–57 (broad region; genes not listed).
- chr8:129,241,228–129,291,275, 3 genes, copy number 13–33: AC103833.2, AC103833.1, RN7SKP206.
- chr8:129,832,301–132,481,095, 28 genes, copy number 19–52: AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3.
- chr9:60,914,407–60,964,196, 5 genes, copy number 11: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:133,351,758–133,361,158, 2 genes, copy number 10: SURF1, SURF2.
- chr9:137,188,660–137,221,581, 5 genes, copy number 9–11: SSNA1, TPRN, TMEM203, NDOR1, RNF208.
- chr9:137,227,502–137,236,555, 2 genes, copy number 9–14: RNF224, SLC34A3.
- chr9:137,306,896–137,459,334, 5 genes, copy number 11–12: EXD3, NOXA1, ENTPD8, NSMF, MIR7114.
- chr10:69,571,698–69,596,436, 7 genes, copy number 9: NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20.
- chr10:70,137,981–70,233,911, 5 genes, copy number 10: TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1.
- chr10:70,389,426–70,447,951, 4 genes, copy number 10–11: CEP57L1P1, EIF4EBP2, NODAL, AC022532.1.
- chr11:112,967–186,136, 5 genes, copy number 11 (within-gene range 8–11): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr12:16,548,372–32,993,754, 286 genes, copy number 15–18 (within-gene range 5–18) (broad region; genes not listed).
- chr12:115,957,905–116,277,693, 6 genes, copy number 10: MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1.
- chr12:119,667,864–119,877,320, 4 genes, copy number 9 (within-gene range 7–9): PRKAB1, CIT, AC002563.1, MIR1178.
- chr12:120,740,470–120,904,358, 3 genes, copy number 9: AC069234.1, SPPL3, ARF1P2.
- chr12:122,503,454–122,634,673, 4 genes, copy number 9: RSRC2, KNTC1, AC026333.1, AC026333.4.
- chr16:629,239–648,474, 3 genes, copy number 21 (within-gene range 5–21): WFIKKN1, METTL26, MCRIP2.
- chr16:678,504–705,808, 7 genes, copy number 9–24 (within-gene range 7–24): LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16.
- chr20:62,841,005–63,104,386, 14 genes, copy number 9 (within-gene range 8–9): TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A.
- chr20:63,540,810–63,547,504, 2 genes, copy number 9: SRMS, AL121829.2.
- chr20:63,738,270–63,744,050, 2 genes, copy number 9 (within-gene range 5–9): AL121845.2, SLC2A4RG.

Autosomal genes at a single copy (total copy number 1): 61. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
